Gene-level copy-number profile of tumor specimen TCGA-VS-A953-01A from TCGA case TCGA-VS-A953, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 63.7 years (23,277 days).
Specimen TCGA-VS-A953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c4d488bf-d211-45e2-933a-807ba0d7d35a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A953-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6420a6c8-97ae-4fb5-8aee-e4cf2b966aef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 5; copy number 2: 320; copy number 3: 10,493; copy number 4: 23,791; copy number 5: 14,600; copy number 6: 5,680; copy number 7: 1,613; copy number 8: 1,209; copy number 9: 1,681; copy number 10: 73; copy number 11: 130; copy number 12: 134; copy number 13: 10; copy number 14: 16; copy number 15: 35; copy number 19: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A953-01A-11D-A386-01): tumor purity 0.88, ploidy 4.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,478,484–73,714,384, 17 genes (within-gene range 0–6): HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6, NDUFB8P1, DNAL1, RNU6-240P, AC006146.1, PNMA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,084 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,549,089–145,066,685, 1,533 genes, copy number 9–15 (broad region; genes not listed).
- chr16:12,745,873–12,761,162, 2 genes, copy number 9: AC109597.1, AC109597.2.
- chr16:15,434,475–15,932,294, 16 genes, copy number 14 (within-gene range 7–14): BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20.
- chr16:34,962,970–35,912,516, 81 genes, copy number 9 (broad region; genes not listed).
- chr16:52,436,417–52,547,802, 1 gene, copy number 11 (within-gene range 5–11): TOX3.
- chr16:69,565,094–69,941,741, 11 genes, copy number 10 (within-gene range 7–10): NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62.
- chr16:80,040,662–80,167,577, 2 genes, copy number 10 (within-gene range 4–10): AC092130.1, AC022166.1.
- chr20:4,120,980–6,220,759, 59 genes, copy number 12: SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3.
- chr20:6,731,080–16,053,197, 92 genes, copy number 9–19 (within-gene range 5–19) (broad region; genes not listed).
- chr20:15,021,553–20,360,703, 91 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr20:23,685,640–25,162,061, 31 genes, copy number 9: CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1.
- chr20:32,277,651–32,743,567, 14 genes, copy number 11 (within-gene range 7–11): KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7.
- chr20:43,222,206–47,188,844, 151 genes, copy number 11–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
